Gene-level copy-number profile of specimen HCM-CSHL-0179-C25-85A from HCMI case HCM-CSHL-0179-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 60.3 years (22,008 days).
Specimen HCM-CSHL-0179-C25-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 417ddbbe-450e-4011-977a-435bdd347f5b.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0179-C25-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,229 have no estimate.
https://portal.gdc.cancer.gov/files/05582b97-9d5e-4d0d-80a8-207dcd0193c4

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,345; copy number 2: 9,496; copy number 3: 17,440; copy number 4: 18,417; copy number 5: 8,385; copy number 6: 2,614; copy number 7: 100; copy number 8: 83; copy number 9: 466; copy number 10: 7; copy number 20: 3; copy number 21: 2; copy number 25: 36.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 514 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:19,215,615–19,336,715, 1 gene, copy number 25 (within-gene range 7–25): EPN2.
- chr17:19,296,596–19,897,287, 40 genes, copy number 20–25: EPN2-AS1, B9D1, MIR1180, AC124066.1, MAPK7, MFAP4, RNF112, AC004448.3, AC004448.2, LINC02094, AC004448.4, RPS2P46, AC004448.1, SLC47A1, RPL17P43, SNORA59B, AC025627.1, SLC47A1P1, AC025627.2, AC025627.3, AC025627.4, MTND1P14, NMTRQ-TTG12-1, MTND2P12, MTCO1P39, SLC47A1P2, ALDH3A2, AC115989.1, Y_RNA, AC005722.2, SLC47A2, AC005722.3, AC005722.4, ALDH3A1, AC005722.1, ULK2, NDUFB4P3, AC015726.3, AC015726.2, AC015726.1.
- chr19:51,410,020–52,426,202, 72 genes, copy number 9–10 (broad region; genes not listed).
- chr19:53,223,973–53,261,837, 4 genes, copy number 9: NDUFV2P1, ZNF677, AC092070.3, VN1R2.
- chr19:53,299,051–53,876,435, 89 genes, copy number 9 (broad region; genes not listed).
- chr19:54,094,668–55,674,716, 140 genes, copy number 9 (within-gene range 8–9) (broad region; genes not listed).
- chr19:55,759,014–55,932,336, 6 genes, copy number 9: RFPL4A, RFPL4AL1, RFPL4AP1, NLRP11, NLRP4, NLRP13.
- chr19:56,087,366–56,626,481, 40 genes, copy number 9–10: ZNF787, Y_RNA, AC024580.2, ZNF444, AC024580.1, GALP, ZSCAN5B, ZSCAN5C, AC011506.1, ZSCAN5A, ZSCAN5DP, EDDM13, AC006116.5, AC006116.7, Y_RNA, VN2R17P, AC006116.1, AC006116.3, AC006116.2, AC006116.6, AC006116.8, ZNF542P, ZNF582, AC006116.9, SLC25A36P1, AC006116.4, ZNF582-AS1, ZNF583, ZNF667, ZNF667-AS1, AC004696.2, AC004696.1, ZNF471, AC005498.1, AC005498.2, ZFP28, AC005498.3, ZNF470, SIGLEC31P, ZNF71.
- chr19:56,643,159–56,671,783, 2 genes, copy number 9: SMIM17, ZNF835.
- chr19:57,175,233–57,330,770, 11 genes, copy number 9: AC025588.1, ZNF264, AURKC, ZNF805, AC005261.3, ZNF460-AS1, ZNF460, AC005261.5, AC005261.1, AC005261.4, ZNF543.
- chr19:57,394,183–58,605,223, 109 genes, copy number 9 (within-gene range 8–9) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 76. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
